Somatic mutation profile of tumor specimen TCGA-MQ-A6BL-01A (aliquot TCGA-MQ-A6BL-01A-11D-A34C-32) from TCGA case TCGA-MQ-A6BL, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mesothelioma, biphasic, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 78.3 years (28,590 days).
Specimen TCGA-MQ-A6BL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15ba1434-3b27-41da-9013-138f76437c7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MQ-A6BL-10A (Blood Derived Normal), aliquot TCGA-MQ-A6BL-10A-01D-A34C-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8131b79-6bb4-42ca-b39a-627f4f85de9a

The open-access MAF lists 43 somatic variants for this specimen: 34 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 22, Silent 9, Frame Shift Del 5, Nonsense Mutation 4, Frame Shift Ins 1, Translation Start Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V0E1 | c.10C>T p.H4Y | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.019); catalogued as COSV54185777; called by muse, mutect2, varscan2
- AWAT1 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs765416872, COSV100997176; called by muse, mutect2, varscan2
- CLIC5 | c.961G>A p.A321T (on ENST00000185206 / NM_001370649.1; = p.A162T on NM_016929.5) | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as rs922400240; called by muse, mutect2, varscan2
- GFRAL | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 32/191 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.219); catalogued as rs757540959, COSV61231407, COSV61232771; called by muse, mutect2, varscan2
- GLI1 | c.925C>T p.R309W | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs369128119; called by muse, mutect2, varscan2
- HTT | c.1727C>G p.S576* | Nonsense Mutation (SNP) | VAF 12/84 reads (14%) | catalogued as COSV61862694; called by muse, mutect2, varscan2
- LATS2 | c.2320G>A p.E774K | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104430060; called by muse, mutect2, varscan2
- OR6C76 | c.244A>T p.I82F | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); catalogued as COSV60389729; called by muse, mutect2, varscan2
- PDYN | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150455107; called by muse, mutect2, varscan2
- S100A7L2 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1164134401, COSV64195155; called by muse, mutect2, varscan2
- S1PR4 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776302365; called by muse, mutect2, varscan2
- ZFP36 | c.401A>G p.H134R (on ENST00000594442; = p.H128R on NM_003407.5) | Missense Mutation (SNP) | VAF 38/324 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1330171117; called by muse, mutect2, varscan2
- ZNF536 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs941188446, COSV100835611; called by muse, mutect2, varscan2
- AL031777.2 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- AP5M1 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by mutect2, varscan2
- ARHGAP33 | c.2647_2666del p.F883Rfs*38 | Frame Shift Del (DEL) | VAF 10/84 reads (12%) | called by mutect2, pindel
- ARHGEF25 | c.1439_1451del p.E480Gfs*100 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by mutect2, varscan2
- ASCC3 | c.6098_6104del p.L2033* | Frame Shift Del (DEL) | VAF 9/49 reads (18%) | called by mutect2, pindel, varscan2
- ATP6V1H | c.892del p.E298Kfs*12 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | called by mutect2, pindel, varscan2
- C8orf33 | c.383A>T p.Q128L | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- CCDC66 | c.2821G>T p.E941* (on ENST00000394672 / NM_001353147.1; = p.E907* on NM_001012506.5 and 6 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2, varscan2
- CDHR1 | c.1447G>C p.E483Q | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DOCK2 | c.4260G>C p.R1420S | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- EIF4A1 | c.969C>G p.S323R | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- ERICH3 | c.453del p.R152Dfs*24 | Frame Shift Del (DEL) | VAF 14/65 reads (22%) | called by mutect2, pindel, varscan2
- FBLL1 | c.916C>A p.Q306K | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- INVS | c.2692C>A p.L898I | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MATK | c.1295A>T p.E432V (on ENST00000310132 / NM_139355.3; = p.E433V on NM_002378.4) | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- MROH1 | c.1218G>A p.V406= | Splice Region (SNP) | VAF 11/106 reads (10%) | called by muse, mutect2, varscan2
- OR6K2 | c.911dup p.H305Afs*6 | Frame Shift Ins (INS) | VAF 6/43 reads (14%) | called by pindel, varscan2
- P4HA1 | c.374A>C p.E125A | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PLOD3 | c.1953C>G p.N651K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SLC25A19 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 10/49 reads (20%) | called by muse, mutect2, varscan2
- ZKSCAN5 | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- ABCB6 | c.2037C>G p.T679= | Silent (SNP) | VAF 20/130 reads (15%) | called by muse, mutect2, varscan2
- FRYL | c.4467T>A p.A1489= | Silent (SNP) | VAF 15/98 reads (15%) | called by muse, mutect2, varscan2
- HDAC5 | c.1038C>T p.L346= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV56817632; called by muse, mutect2, varscan2
- HIPK4 | c.315C>T p.F105= | Silent (SNP) | VAF 18/174 reads (10%) | catalogued as rs764449728; called by mutect2, varscan2
- HOXB7 | c.240C>T p.L80= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs777513955, COSV99493840; called by muse, mutect2, varscan2
- KDM4C | c.2484C>T p.S828= | Silent (SNP) | VAF 8/37 reads (22%) | called by muse, mutect2, varscan2
- NXF3 | c.1263G>T p.V421= | Silent (SNP) | VAF 24/87 reads (28%) | called by muse, mutect2, varscan2
- PDZD7 | c.384C>T p.C128= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as rs573879477, COSV64646469; called by muse, mutect2, varscan2
- SDK1 | c.4863G>C p.L1621= | Silent (SNP) | VAF 13/65 reads (20%) | called by muse, mutect2, varscan2
